MMRF case MMRF_1913 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/434e9cd3-eee2-4c17-85aa-b057901483bc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.6 years (29,059 days); ISS stage: III; Days to last known disease status: 1,069 days (2.9 years); Days to last follow up: 1,069 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 369 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 651 days (1.8 years); Days to treatment end: 662 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 651 days (1.8 years); Days to treatment end: 676 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 677 days (1.9 years); Days to treatment end: 683 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 677 days (1.9 years); Days to treatment end: 733 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 684 days (1.9 years); Days to treatment end: 704 days (1.9 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 705 days (1.9 years); Days to treatment end: 733 days (2.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 804 days (2.2 years); Days to treatment end: 936 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 1): M Protein 6.12 g/dL; Immunoglobulin G 3.85 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 8.5 µg/mL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 23.2 mmol/L; Calcium 2.5 mmol/L; Total Protein 6.66 g/dL; Glucose 4.18 mmol/L; C-Reactive Protein 0.087 mg/dL.
- Day 67 (ECOG 1): M Protein 0.13 g/dL; Hemoglobin 8.06 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 165 µmol/L; Calcium 2.4 mmol/L; Albumin 37.8 g/L; Total Protein 6.24 g/dL.
- Day 151 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 22.7 mg/dL; Immunoglobulin G 5.05 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 22.8 mmol/L; Calcium 2.38 mmol/L; Albumin 38.3 g/L; Total Protein 6.59 g/dL; Glucose 6.6 mmol/L.
- Day 256 (ECOG 0): Hemoglobin 9.05 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 10.6 mmol/L; Calcium 2.4 mmol/L; Albumin 37.5 g/L; Total Protein 6.19 g/dL; Glucose 4.7 mmol/L.
- Day 340 (ECOG 0): M Protein 0.32 g/dL; Immunoglobulin G 6.53 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 9.61 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 20.7 mmol/L; Calcium 2.4 mmol/L; Albumin 40.4 g/L; Total Protein 6.52 g/dL; Glucose 4.24 mmol/L.
- Day 452 (ECOG 0): M Protein 1.87 g/dL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 9.98 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 11 mmol/L; Calcium 2.4 mmol/L; Total Protein 6.71 g/dL; Glucose 4.9 mmol/L.
- Day 547 (ECOG 0): M Protein 4.56 g/dL; Immunoglobulin G 4.94 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 143 µmol/L; Calcium 2.35 mmol/L; Albumin 39.3 g/L; Total Protein 6.62 g/dL; Glucose 4.51 mmol/L.
- Day 628 (ECOG 0): M Protein 0.58 g/dL; Beta 2 Microglobulin 4.9 µg/mL; Hemoglobin 9.3 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 158 µmol/L; Albumin 41 g/L; Total Protein 6.97 g/dL; Glucose 4.84 mmol/L.
- Day 705 (ECOG 2): M Protein 2.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 210 mg/dL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 179 µmol/L; Calcium 2.3 mmol/L; Albumin 37.8 g/L; Total Protein 6.23 g/dL; Glucose 5.17 mmol/L.
- Day 790 (ECOG 1): M Protein 2.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 339 mg/dL; Hemoglobin 9.18 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 159 µmol/L; Albumin 37.7 g/L; Total Protein 6.19 g/dL; Glucose 5.34 mmol/L.
- Day 874 (ECOG 1): M Protein 0.13 g/dL; Immunoglobulin G 3.08 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 6.2 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 145 µmol/L; Calcium 2.2 mmol/L; Albumin 35.5 g/L; Total Protein 5.66 g/dL; Glucose 5.01 mmol/L.
- Day 957 (ECOG 1): M Protein 2.26 g/dL; Immunoglobulin G 3.53 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 154 µmol/L; Calcium 2.35 mmol/L; Albumin 39.1 g/L; Total Protein 6.29 g/dL; Glucose 2.92 mmol/L.
- Day 1,069 (ECOG 1): M Protein 0.53 g/dL; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 173 µmol/L; Calcium 2.33 mmol/L; Albumin 38.5 g/L; Total Protein 6.75 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day -14: Weight: 71 kg; Height: 170 cm.

Biospecimens (3 samples)
- Sample MMRF_1913_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 628 days (1.7 years).
- Sample MMRF_1913_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 628 days (1.7 years).
- Sample MMRF_1913_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 790 days (2.2 years).
